CCDI case PBBZWJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3145a5b5-6cb4-4730-a5b4-63c48a154f76

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.1 years (1,502 days).

Biospecimens (3 samples)
- Sample 0DLSX3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLSXA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLSYF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
